Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AO, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AO-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Neck: Right neck level 2
2. Right neck level 3
3. Right neck level 4
4. Central compartment total thyroidectomy (stitch right superior pole)
5. Right lateral central right compartment

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 6 (right neck level II) dissection specimen
2. No pathological diagnosis: Lymph nodes, 3 (right neck level III) dissection specimen
3. Metastatic papillary thyroid carcinoma: Lymph nodes, 3 of 9 (right neck level IV) dissection specimen
4. Multifocal papillary carcinoma, dominant widely invasive mixed classical and follicular variant, 3.0 cm, right; focal nonspecific thyroiditis and mild reactive C-cell hyperplasia: Thyroid
No pathological diagnosis: Lymph node, left perithyroidal
No pathological diagnosis: Parathyroid, right perithyroidal
Metastatic papillary thyroid carcinoma with focal extranodal extension: Lymph nodes, 5 of 5, central compartment
- Total thyroidectomy with central neck dissection specimen
5. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 2 (right lateral central compartment) dissection specimen

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Other: Total thyroidectomy with central and right neck dissection

Fresh

Intact

Right lobe:

4.6 cm

3.5 cm

3.0 cm

Left lobe:

ICD-0-3
path: carcinoma, papillary + follicular 8240/3
CCCF: carcinoma, papillary, thyroid 8240/3
site: thyroid, NOS C73.9 lw
10/21/11

[page 2 of 3]
4.5 cm
2.4 cm
1.3 cm
Isthmus +/- pyramidal lobe:
2.0 cm
0.5 cm
1.5 cm
Central compartment:
9.5 cm
2.0 cm
1.5 cm
Specimen Weight: 40.7 g
Tumor Focality: Multifocal, bilateral
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 3.0cm
Additional dimension: 2.3 cm
Additional dimension: 1.8 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 0.05cm
Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 26
Number of regional lymph nodes involved: 10
Lymph Node, Extranodal Extension Present
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis, focal (nonspecific)
Parathyroid gland(s), within normal limits
C-cell hyperplasia
Other: C-cell hyperplasia is mild and reactive in nature

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 3 of 3]
Electronically verified by:
MD

Clinical History
Thyroid carcinoma

Gross Description

1. The specimen labeled with the patient's name and "right neck level 2". It consists of portion of fibroadipose tissue that measures 4.5 x 2.5 x 1.5 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.2 to 0.9 x 0.6 x 0.3 cm are identified grossly. Representative sections are submitted.
1A-B multiple nodes
2. The specimen labeled with the patient's name and "right neck level 3". It consists of portion of fibroadipose tissue that measures 3.7 x 2.8 x 1.5 cm. Multiple lymph nodes ranging from 1.5 x 1 x 0.6 cm to 1.8 x 0.8 x 0.4 cm are identified grossly. Representative sections are submitted.
2A-C one node bisected each cassette
3. The specimen labeled with the patient's name and "right neck level 4". It consists of portion of fibroadipose tissue that measures 9 x 4.5 x 2.3 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 3.5 x 3 x 2.2 cm are identified grossly. The largest node is solid and involved. Representative sections are submitted.
3A-B multiple nodes
3C one node bisected
3D representative sections of the largest node
3E remaining node after decal
4. The specimen labeled with the patient's name and as "central compartment total thyroidectomy stitch right superior pole" consists of a thyroid gland that is oriented with suture at the right superior pole and weighs 40.7 g. The right lobe measures 4.6 cm SI x 3.5 cm ML x 3 cm AP, the left lobe measures 4.5 cm SI x 2.4 cm ML x 1.3 cm AP and the isthmus measures 2 cm SI x 0.5 cm ML x 1.5 cm AP. The central lower soft tissue measures 9.5 x 2 x 1.5 cm containing multiple nodes that ranging in size from 0.7 x 0.6 x 0.6 cm to 1.4 x 1.4 x 1 cm, 3 of which are calcified. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands are identified grossly. Multiple lymph nodes are identified in the lower central. The upper to lower pole of the right lobe contains one well delineated partly calcified nodule that measures 3.0 cm SI x 1.8 cm ML x 2.3 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
1A-J right lobe, superior to inferior (remaining tumor being submitted after decal)
1K isthmus
1L-U left lobe, superior to inferior
1V one node
1W-X one node trisected
1Y one node
1Z one node bisected
1AA one node bisected
1AB-1AI remaining tumor after decal
5. The specimen labeled with the patient's name and "right lateral central right compartment". It consists of portion of fibroadipose tissue that measures 3.7 x 2.5 x 1 cm. Two lymph nodes ranging from 0.5 x 0.4 x 0.2 to 2.4 x 1.3 x 1.4 cm are identified grossly. Representative sections are submitted.
A one node bisected
B one node sectioned

Source: NCI Genomic Data Commons file f2e61e47-ca7c-4df5-88e8-83cb1342717b (TCGA-EM-A3AO.ED64D5D3-1CAF-4632-BDED-4A4194CB68A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).